Somatic mutation profile of tumor specimen 0DP6I4 from CCDI case PBCDAS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain stem; Age at diagnosis: 1.5 years (533 days).
Specimen 0DP6I4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abcc7773-831a-436d-a84c-66d8ef340c86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP6HJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a9b55d8-2578-493c-bbe2-d351a5a55cb7

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.2068G>T p.G690W | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100336630, COSV60659184; called by muse, mutect2, varscan2
- EXOC3 | c.1776+91G>A | Intron (SNP) | VAF 11/64 reads (17%) | catalogued as rs1427498635; called by muse, mutect2, varscan2
- FARP1 | c.*4775A>T | 3'UTR (SNP) | VAF 62/144 reads (43%) | called by muse, mutect2, varscan2
